Somatic mutation profile of tumor specimen TCGA-AA-A01V-01A (aliquot TCGA-AA-A01V-01A-23W-A096-10) from TCGA case TCGA-AA-A01V, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 59.7 years (21,792 days).
Specimen TCGA-AA-A01V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 766f0fa2-efbc-43d2-a133-f40e18d4de12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A01V-11A (Solid Tissue Normal), aliquot TCGA-AA-A01V-11A-11W-A096-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67ec25c0-6891-438c-b7f8-30518344f0b5

The open-access MAF lists 131 somatic variants for this specimen: 95 protein-altering or splice-affecting, 34 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 34, Nonsense Mutation 7, Frame Shift Ins 3, Frame Shift Del 3, Intron 2, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 100/260 reads (38%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- DHX30 | c.1478G>A p.R493H (on ENST00000445061 / NM_138615.3; = p.R454H on NM_014966.3) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519436, COSV53140099; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 275/728 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3155C>A p.T1052K | Missense Mutation (SNP) | VAF 104/254 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as COSV55882314, COSV55947907; called by muse, mutect2, varscan2
- RAF1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 99/262 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs80338796, CM073301, COSV52574378, COSV52579821; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 85/246 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50994862; called by muse, mutect2, varscan2
- AADACL4 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 131/356 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs370456693; called by muse, mutect2, varscan2
- AC007040.2 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as rs782474395, COSV55592699; called by muse, mutect2, varscan2
- ACTR2 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 224/626 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); catalogued as rs17851188, COSV53202221; called by muse, mutect2, varscan2
- ACVR2A | c.1418del p.G473Dfs*3 | Frame Shift Del (DEL) | VAF 365/630 reads (58%) | catalogued as COSV99604906; called by mutect2, pindel, varscan2
- ACVR2B | c.811-2A>G p.X271_splice | Splice Site (SNP) | VAF 122/317 reads (38%) | catalogued as COSV61703023; called by muse, mutect2, varscan2
- AFAP1L2 | c.2279C>G p.T760S | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.063); catalogued as rs750411935, COSV58416904; called by muse, mutect2, varscan2
- ANK1 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); catalogued as rs777258799, COSV55887879, COSV55898732; called by muse, mutect2, varscan2
- APC | c.2819C>A p.S940* | Nonsense Mutation (SNP) | VAF 83/212 reads (39%) | catalogued as CM095524, COSV57320637; called by muse, mutect2, varscan2
- APC | c.4256G>A p.S1419N | Missense Mutation (SNP) | VAF 130/382 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as CD084034, CX021237, COSV57362800, COSV57400307; called by muse, varscan2
- ARAP2 | c.4849G>T p.E1617* | Nonsense Mutation (SNP) | VAF 139/371 reads (37%) | catalogued as COSV100394591; called by muse, mutect2, varscan2
- BCHE | c.1761T>A p.N587K | Missense Mutation (SNP) | VAF 268/780 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as COSV100012472; called by muse, mutect2, varscan2
- C2CD3 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 285/771 reads (37%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.928); catalogued as COSV58096103, COSV58097538; called by muse, mutect2, varscan2
- C8B | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 89/248 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.263); catalogued as rs199592536, COSV100980765; called by muse, mutect2, varscan2
- CCNA2 | c.926C>G p.P309R | Missense Mutation (SNP) | VAF 144/358 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99144905; called by muse, mutect2, varscan2
- CDCA2 | c.2981G>C p.G994A | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.037); catalogued as COSV100398861; called by muse, mutect2, varscan2
- DCX | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 376/472 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1230386660, COSV57572451; called by muse, mutect2, varscan2
- DDX27 | c.1421A>G p.K474R | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.235); catalogued as COSV100873330; called by muse, mutect2, varscan2
- DLC1 | c.3532C>T p.P1178S (on ENST00000276297 / NM_001348081.2; = p.P741S on NM_006094.5) | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); catalogued as rs1335302132, COSV52315893; called by muse, mutect2, varscan2
- DLGAP1 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 94/284 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs1227331145, COSV59819777; called by muse, mutect2, varscan2
- DMXL1 | c.4292C>T p.T1431M | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.463); catalogued as rs752622065, COSV100223883; called by muse, mutect2, varscan2
- EIF4E1B | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as rs779126438, COSV53780811; called by muse, mutect2
- EOGT | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV55152555; called by muse, mutect2, varscan2
- EPHA4 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 183/230 reads (80%) | SIFT tolerated (0.59); PolyPhen benign (0.051); catalogued as rs537081277, COSV56038674; called by muse, mutect2, varscan2
- FAT4 | c.6229C>A p.P2077T | Missense Mutation (SNP) | VAF 89/221 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.57); catalogued as rs1198005907, COSV58670873; called by muse, mutect2, varscan2
- FAT4 | c.6230C>G p.P2077R | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.014); catalogued as COSV100628512; called by muse, mutect2, varscan2
- FBN2 | c.8494del p.I2832Sfs*65 | Frame Shift Del (DEL) | VAF 133/399 reads (33%) | catalogued as COSV52529176; called by mutect2, pindel, varscan2
- FLG | c.2803G>T p.G935W | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV64244874; called by muse, mutect2, varscan2
- FXR1 | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 114/252 reads (45%) | catalogued as COSV99976356; called by muse, mutect2, varscan2
- GLRX3 | c.830A>G p.E277G | Missense Mutation (SNP) | VAF 322/882 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100487914; called by muse, mutect2, varscan2
- GRAMD2A | c.520A>G p.R174G | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59034489; called by muse, mutect2
- GRIK1 | c.2584C>T p.R862W | Missense Mutation (SNP) | VAF 95/268 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs775408657, COSV58714756; called by muse, mutect2, varscan2
- H1-2 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs527943061, COSV59191978; called by muse, mutect2, varscan2
- HECTD3 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 102/288 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs113744661; called by muse, mutect2, varscan2
- HERC2 | c.10006G>A p.E3336K | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs773792045, COSV99873364; called by muse, mutect2, varscan2
- IGHA2 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs782281585; called by muse, mutect2, varscan2
- KCNMA1 | c.2725C>T p.R909W (on ENST00000286628 / NM_001161352.2; = p.R851W on NM_002247.4) | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228444398, COSV54247340; called by muse, mutect2, varscan2
- KRT76 | c.1295C>A p.A432D | Missense Mutation (SNP) | VAF 95/252 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60121169; called by muse, mutect2, varscan2
- MMAB | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756414548, CM061118, COSV99904528; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MPPED1 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61988288; called by muse, mutect2, varscan2
- MUC13 | c.1400T>G p.L467R | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60700467; called by muse, mutect2, varscan2
- MYF5 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57355794; called by muse, mutect2, varscan2
- NCKAP5 | c.4962T>A p.C1654* | Nonsense Mutation (SNP) | VAF 198/459 reads (43%) | catalogued as COSV100491813; called by muse, mutect2, varscan2
- NCKAP5 | c.1145G>T p.S382I | Missense Mutation (SNP) | VAF 83/269 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV100491817; called by muse, mutect2, varscan2
- NLRP12 | c.2735C>T p.T912M | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs750086255, COSV100144938; called by muse, mutect2, varscan2
- NRXN1 | c.1612G>T p.V538L | Missense Mutation (SNP) | VAF 185/535 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.404); catalogued as COSV58472653; called by muse, mutect2, varscan2
- OR13C9 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765101156, COSV99403434; called by muse, mutect2, varscan2
- OR6N1 | c.461C>A p.A154D | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100625164; called by muse, mutect2, varscan2
- PAPPA2 | c.958G>C p.G320R | Missense Mutation (SNP) | VAF 87/249 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as COSV100866426, COSV62782064; called by muse, mutect2, varscan2
- PCDH10 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99993059; called by muse, mutect2, varscan2
- PITX2 | c.151A>T p.K51* | Nonsense Mutation (SNP) | VAF 33/82 reads (40%) | catalogued as rs908902146, COSV61585626; called by muse, mutect2, varscan2
- PKD2L2 | c.1027C>A p.L343I | Missense Mutation (SNP) | VAF 298/712 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.222); catalogued as COSV51799530; called by muse, mutect2, varscan2
- PLA1A | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527318106, COSV56332875; called by muse, mutect2, varscan2
- POMT1 | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 201/497 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.045); catalogued as COSV61226823; called by muse, mutect2, varscan2
- PRAG1 | c.2327C>T p.S776L | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.477); catalogued as rs199990185, COSV58164214; called by muse, varscan2
- PTPRK | c.3584C>T p.A1195V (on ENST00000368215 / NM_001291984.2; = p.A1196V on NM_002844.4) | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV63902821; called by muse, mutect2, varscan2
- RNF169 | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 90/218 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1048312164, COSV55136470; called by muse, mutect2, varscan2
- RPAIN | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV56706005, COSV56706908; called by muse, mutect2, varscan2
- RPS23 | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 81/221 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as COSV56994285; called by muse, mutect2, varscan2
- RSPH10B2 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 108/620 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs754477592, COSV51867563; called by muse, mutect2, varscan2
- SALL1 | c.2234C>T p.T745M | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51754374; called by muse, mutect2, varscan2
- SHISAL1 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs757448925, COSV66987684, COSV66987790; called by muse, mutect2, varscan2
- SLC18A3 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100340106; called by muse, mutect2, varscan2
- SLC35F3 | c.278A>C p.K93T (on ENST00000366617 / NM_001300845.1; = p.K162T on NM_173508.4) | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1211957005, COSV64020711; called by muse, mutect2, varscan2
- SLC39A11 | c.832G>A p.V278I (on ENST00000542342 / NM_001159770.2; = p.V271I on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV55295481; called by muse, mutect2, varscan2
- SOX17 | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as COSV52024411, COSV52026987; called by muse, mutect2
- SPINK5 | c.1938C>A p.C646* | Nonsense Mutation (SNP) | VAF 60/146 reads (41%) | catalogued as COSV56263366; called by muse, mutect2, varscan2
- SYNDIG1 | c.618G>T p.E206D | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as COSV65237541; called by muse, mutect2, varscan2
- TBC1D28 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 125/319 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs763855902, COSV61507828; called by muse, mutect2, varscan2
- TCHH | c.2054T>A p.L685Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV100915032; called by muse, mutect2, varscan2
- TMEM51 | c.250A>T p.S84C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV65691255; called by muse, mutect2, varscan2
- TRIM49 | c.874C>A p.H292N | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV61671395; called by muse, mutect2, varscan2
- TRPM7 | c.2159C>T p.T720I | Missense Mutation (SNP) | VAF 197/514 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100539810, COSV57922775; called by muse, mutect2, varscan2
- TRPS1 | c.1249A>T p.I417L (on ENST00000220888 / NM_001330599.2; = p.I430L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/245 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as COSV99630615; called by muse, mutect2, varscan2
- TTC37 | c.1421A>T p.D474V | Missense Mutation (SNP) | VAF 314/830 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100706608; called by muse, mutect2, varscan2
- TTN | c.90961A>T p.N30321Y (on ENST00000591111; = p.N22897Y on NM_003319.4) | Missense Mutation (SNP) | VAF 144/410 reads (35%) | PolyPhen benign (0.115); catalogued as COSV100611074; called by muse, mutect2, varscan2
- VRK3 | c.972G>T p.L324F | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100371587; called by muse, mutect2, varscan2
- WDR19 | c.1707T>G p.D569E | Missense Mutation (SNP) | VAF 161/428 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.199); catalogued as COSV56467637; called by muse, mutect2, varscan2
- WDR43 | c.544A>G p.M182V | Missense Mutation (SNP) | VAF 277/700 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.05); catalogued as COSV56099333; called by muse, mutect2, varscan2
- YIPF7 | c.670T>G p.F224V | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as COSV60657468; called by muse, mutect2, varscan2
- ZDHHC15 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 82/117 reads (70%) | SIFT tolerated (0.67); PolyPhen benign (0.206); catalogued as COSV64904299; called by muse, mutect2, varscan2
- ZNF429 | c.1175C>A p.T392N | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV61917494; called by muse, mutect2, varscan2
- ZNF793 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 83/229 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV71325136; called by muse, mutect2, varscan2
- CDCA2 | c.1558_1559del p.S520Cfs*13 | Frame Shift Del (DEL) | VAF 282/904 reads (31%) | called by pindel, varscan2
- DOCK2 | c.3962dup p.N1321Kfs*10 | Frame Shift Ins (INS) | VAF 57/182 reads (31%) | called by mutect2, pindel, varscan2
- ELF3 | c.567dup p.S190Lfs*6 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- IGHV3-11 | c.112A>G p.R38G | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MRC1 | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 516/1336 reads (39%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.97); called by mutect2, varscan2
- PCLO | c.7010_7015dup p.E2337_T2338dup | In Frame Ins (INS) | VAF 57/152 reads (38%) | called by mutect2, varscan2
- SOX9 | c.1321dup p.D441Gfs*137 | Frame Shift Ins (INS) | VAF 150/381 reads (39%) | called by mutect2, pindel, varscan2
- ACER2 | c.327C>T p.F109= | Silent (SNP) | VAF 410/1093 reads (38%) | catalogued as COSV61821118; called by muse, mutect2, varscan2
- ACP7 | c.1275C>A p.V425= | Silent (SNP) | VAF 285/664 reads (43%) | catalogued as COSV58700155; called by muse, mutect2, varscan2
- ATP10D | c.1008C>T p.G336= | Silent (SNP) | VAF 54/143 reads (38%) | catalogued as rs377297409; called by muse, mutect2, varscan2
- CCER1 | c.477G>A p.P159= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs1274085445, COSV62645818; called by muse, varscan2
- CDH7 | c.1767C>T p.G589= | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as rs1454531414, COSV59891111; called by muse, mutect2
- CTC1 | c.2223C>A p.L741= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as COSV59854257; called by muse, mutect2, varscan2
- DHX15 | c.1671A>G p.E557= | Silent (SNP) | VAF 174/482 reads (36%) | catalogued as COSV61028309; called by muse, mutect2, varscan2
- DNAH10 | c.5550G>A p.T1850= (on ENST00000409039; = p.T1789= on NM_207437.3) | Silent (SNP) | VAF 72/168 reads (43%) | catalogued as rs751667257, COSV68994548; called by muse, mutect2, varscan2
- DNAH7 | c.4659G>A p.S1553= | Silent (SNP) | VAF 83/95 reads (87%) | catalogued as rs777461243, COSV100416370, COSV56774864; called by muse, mutect2, varscan2
- EXOSC9 | c.633A>G p.E211= | Silent (SNP) | VAF 137/397 reads (35%) | catalogued as COSV54666951; called by muse, mutect2, varscan2
- FAT4 | c.14634T>C p.S4878= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV58697713; called by muse, mutect2, varscan2
- FRYL | c.5115T>G p.P1705= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as COSV51953958; called by muse, mutect2, varscan2
- GABPA | c.1002C>T p.D334= | Silent (SNP) | VAF 136/301 reads (45%) | catalogued as rs761400758, COSV61397018; called by muse, mutect2, varscan2
- GLIS1 | c.963G>A p.P321= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs148036745; called by muse, mutect2
- GNA13 | c.363G>A p.K121= | Silent (SNP) | VAF 61/204 reads (30%) | catalogued as rs751359082, COSV71474380, COSV71475028; called by muse, mutect2, varscan2
- GOLGA2 | c.1599C>T p.L533= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV68597446; called by muse, mutect2, varscan2
- HMCN1 | c.15741C>T p.N5247= | Silent (SNP) | VAF 205/479 reads (43%) | catalogued as COSV54919235; called by muse, mutect2, varscan2
- HTT | c.2121G>A p.V707= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV61865589; called by muse, mutect2, varscan2
- IL10 | c.321G>A p.A107= | Silent (SNP) | VAF 129/334 reads (39%) | catalogued as rs560908141, COSV65594761; called by muse, mutect2, varscan2
- JCAD | c.2592G>A p.A864= | Silent (SNP) | VAF 49/117 reads (42%) | catalogued as COSV64759030; called by muse, mutect2, varscan2
- KCNE2 | c.297A>G p.Q99= | Silent (SNP) | VAF 59/153 reads (39%) | catalogued as COSV51710643; called by muse, mutect2, varscan2
- KCNMA1 | c.3429T>A p.A1143= (on ENST00000286628 / NM_001161352.2; = p.A1085= on NM_002247.4) | Silent (SNP) | VAF 65/194 reads (34%) | catalogued as COSV54266810; called by muse, mutect2, varscan2
- KCNU1 | c.2907C>T p.H969= | Silent (SNP) | VAF 124/311 reads (40%) | catalogued as rs752811947, COSV67753072; called by muse, mutect2, varscan2
- MORC1 | c.2415G>A p.S805= | Silent (SNP) | VAF 116/280 reads (41%) | catalogued as rs777002185, COSV51725413, COSV99228207; called by muse, mutect2, varscan2
- MUC16 | c.27513G>A p.S9171= | Silent (SNP) | VAF 77/223 reads (35%) | catalogued as rs372068481; called by muse, mutect2, varscan2
- MUC5B | c.2694C>T p.Y898= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs546384509, COSV71591092; called by muse, mutect2, varscan2
- NBEA | c.5673G>A p.A1891= | Silent (SNP) | VAF 54/186 reads (29%) | catalogued as rs762630117, COSV59759446, COSV59803437; called by muse, mutect2, varscan2
- PPFIA1 | c.3246G>A p.L1082= | Silent (SNP) | VAF 57/136 reads (42%) | catalogued as rs373783497; called by muse, mutect2, varscan2
- RAPSN | c.210C>T p.I70= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as rs773975835, COSV54085003; called by muse, mutect2, varscan2
- SIK3 | c.804C>T p.R268= (on ENST00000445177 / NM_001366686.2; = p.R274= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 155/378 reads (41%) | catalogued as rs781741381, COSV52613629; called by muse, mutect2, varscan2
- TIMD4 | c.363C>T p.N121= | Silent (SNP) | VAF 59/157 reads (38%) | catalogued as rs766204987, COSV50854129, COSV50855085; called by muse, mutect2, varscan2
- VCAN | c.9888C>T p.C3296= | Silent (SNP) | VAF 95/226 reads (42%) | catalogued as rs758458805, COSV54096535; called by muse, mutect2, varscan2
- ZNF211 | c.879C>T p.F293= (on ENST00000347302 / NM_198855.4; = p.F306= on NM_006385.5) | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as COSV53741710, COSV53743863; called by muse, mutect2, varscan2
- ZNF672 | c.669G>T p.G223= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100129201, COSV60638512; called by muse, mutect2, varscan2
- CTBP2 | c.58+12846C>T | Intron (SNP) | VAF 12/32 reads (38%) | catalogued as COSV58343338; called by muse, mutect2, varscan2
- HMGA2 | c.250-36314T>A | Intron (SNP) | VAF 102/323 reads (32%) | catalogued as COSV63591034; called by muse, mutect2, varscan2
